Somatic mutation profile of tumor specimen TCGA-4X-A9FB-01A (aliquot TCGA-4X-A9FB-01A-11D-A423-09) from TCGA case TCGA-4X-A9FB, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 44.3 years (16,175 days).
Specimen TCGA-4X-A9FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e2de0b-debf-4502-aebb-4453f8a0868a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4X-A9FB-10A (Blood Derived Normal), aliquot TCGA-4X-A9FB-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74b96604-2d13-4b33-9b2d-ff35dc5170b9

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMP16 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); called by muse, mutect2
- LMBR1L | c.1146C>A p.P382= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
